CGCI case HTMCP-02-03-01006 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c8ff95b7-c295-4fe6-838d-8740a8cf17df

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 1,575 days (4.3 years).

Diagnoses (1)
1. Combined small cell carcinoma: ICD-O-3 morphology code: 8045/3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 56.5 years (20,636 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,543 days (4.2 years).
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 40; ECOG performance status: 3.
- Days to follow up: 1,543 days (4.2 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -7,719.

Other clinical attributes
- Day -7,719: Comorbidities: HIV/AIDS.
- Day -7,719: Risk factors: HIV/AIDS.
- Day 0: AIDS risk factors: Mycobacterium avium Complex.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Weight: 74.5 kg; Height: 167.2 cm; BMI: 26.6; CD4 count: 65; Haart treatment indicator: Yes; HIV viral load: 345.
- Day 1,543: Nadir CD4 count: 700.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 38; Tobacco smoking quit year: 2009.

Biospecimens (3 samples)
- Sample HTMCP-02-03-01006-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01006-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-03-01006-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Small Cell Squamous Cell Carcinoma; Tumor status: With tumor; Tobacco smoking age started: 24; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Performance status timing: Post-Adjuvant Therapy; Tobacco smoking history indicator: 4.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Lower lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1989; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: Yes; Prior aids conditions: Mycobacterium avium complex or Mycobacterium kansasii disseminated or extrapulmonary; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Method initial path diagnosis: Tumor resection.
